Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI5, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI5-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 5.5 cm; tumor confined to testis in available slides;
no angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

ICD 0.3

Seminoma NOS 9061/3
Site: B Testis NOS
462.9
9/03/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file a7bd7c00-4379-4a26-a795-314907733281 (TCGA-2G-AAI5-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).